Somatic mutation profile of tumor specimen BLGSP-71-08-00030-01A (aliquot BLGSP-71-08-00030-01A-01D-A663-33) from CGCI case BLGSP-71-08-00030, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: female; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 7.4 years (2,706 days).
Specimen BLGSP-71-08-00030-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Ovary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77b93e23-0186-40af-9d66-80dc2b325105.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BLGSP-71-08-00030-10A (Blood Derived Normal), aliquot BLGSP-71-08-00030-10A-01D-A663-33; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b92a588-455e-4d84-8eff-a31a92faf6b8

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 5'Flank 2, Splice Site 2, Silent 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.700T>C p.Y234H | Missense Mutation (SNP) | VAF 5/15 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs864622237, CM137618, COSV52694920, COSV52730114, COSV52730255; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.672+2T>C p.X224_splice | Splice Site (SNP) | VAF 106/215 reads (49%) | hotspot (GDC flag); catalogued as CS034998, CS0910926, COSV52677962, COSV52797769, COSV53179168; called by muse, mutect2, varscan2
- MYC | c.35A>C p.Y12S (on ENST00000377970; = p.Y27S on NM_002467.6) | Missense Mutation (SNP) | VAF 17/307 reads (6%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.932); catalogued as COSV52367275, COSV52368182; called by muse, mutect2
- PTPRZ1 | c.2378C>T p.A793V | Missense Mutation (SNP) | VAF 260/562 reads (46%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- SIN3A | c.2278-1G>A p.X760_splice | Splice Site (SNP) | VAF 103/220 reads (47%) | called by muse, mutect2, varscan2
- PIK3C2G | c.3328C>A p.R1110= (on ENST00000676171; = p.R1069= on NM_004570.5) | Silent (SNP) | VAF 39/100 reads (39%) | catalogued as COSV56808258, COSV99849306; called by muse, mutect2, varscan2
- BCL7A | chr12:122021587 G>A | 5'Flank (SNP) | VAF 15/29 reads (52%) | catalogued as COSV55851056; called by muse, mutect2, varscan2
- MYC | chr8:127735723 G>A | 5'Flank (SNP) | VAF 58/104 reads (56%) | catalogued as COSV52373146; called by muse, varscan2
- TCF4 | c.-532A>C | 5'UTR (SNP) | VAF 121/231 reads (52%) | called by muse, mutect2, varscan2
